Somatic mutation profile of tumor specimen TCGA-OR-A5L3-01A (aliquot TCGA-OR-A5L3-01A-11D-A29I-10) from TCGA case TCGA-OR-A5L3, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 67.8 years (24,763 days).
Specimen TCGA-OR-A5L3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f97f6478-df26-4bea-a9e1-4b9e66f44226.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5L3-10A (Blood Derived Normal), aliquot TCGA-OR-A5L3-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f37e1e68-cbf7-4d9d-9565-41a06dcddd38

The open-access MAF lists 27 somatic variants for this specimen: 19 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 7, Splice Site 2, Intron 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.133T>C p.S45P | Missense Mutation (SNP) | VAF 53/125 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs121913407, COSV62687880, COSV62689248, COSV62696859; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FCRL2 | c.64del p.V23Wfs*14 | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | catalogued as COSV100829832; called by mutect2, pindel, varscan2
- FLCN | c.186C>A p.S62R | Missense Mutation (SNP) | VAF 64/183 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.102); catalogued as COSV99550708; called by muse, mutect2, varscan2
- HECTD1 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs769042936; called by muse, mutect2
- NOMO1 | c.3475G>T p.G1159* | Nonsense Mutation (SNP) | VAF 296/1826 reads (16%) | catalogued as rs1356927598; called by muse, mutect2
- NTF3 | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs1327377537, COSV100451139, COSV100451174; called by muse, mutect2, varscan2
- OR4K5 | c.376A>C p.I126L | Missense Mutation (SNP) | VAF 40/248 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs200386813; called by muse, mutect2, varscan2
- PCDHB5 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV50649838; called by muse, mutect2, varscan2
- CHD2 | c.2675A>G p.Q892R | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- EIF1 | c.323T>C p.L108P | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- GABRB1 | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IWS1 | c.85G>C p.G29R | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- PRKAR1A | c.503-17_513del p.X168_splice | Splice Site (DEL) | VAF 20/48 reads (42%) | called by mutect2, pindel
- RANBP17 | c.2375A>G p.N792S | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- SERPINA7 | c.1164T>A p.D388E | Missense Mutation (SNP) | VAF 93/219 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- SERPINB12 | c.104T>C p.L35P | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SPECC1L | c.237C>G p.C79W | Missense Mutation (SNP) | VAF 77/209 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- TRIB3 | c.1-2A>G p.X1_splice | Splice Site (SNP) | VAF 17/46 reads (37%) | called by muse, mutect2
- VWF | c.1192A>T p.S398C | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCARE | c.1245A>T p.S415= | Silent (SNP) | VAF 53/149 reads (36%) | called by muse, mutect2, varscan2
- PDCD6IP | c.975C>T p.D325= | Silent (SNP) | VAF 50/142 reads (35%) | catalogued as rs1227374034; called by muse, mutect2, varscan2
- RAD50 | c.1789T>C p.L597= | Silent (SNP) | VAF 49/131 reads (37%) | catalogued as rs966088598; called by muse, mutect2, varscan2
- SLC25A16 | c.900C>G p.L300= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV99770296; called by muse, varscan2
- SLC5A7 | c.1704C>T p.S568= | Silent (SNP) | VAF 10/21 reads (48%) | called by muse, mutect2, varscan2
- SPTBN4 | c.5520C>T p.F1840= | Silent (SNP) | VAF 39/124 reads (31%) | catalogued as COSV58948975; called by muse, mutect2, varscan2
- TTLL5 | c.1497C>T p.L499= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs778083827, COSV54032062; called by muse, mutect2, varscan2
- CCDC18 | c.-3+377C>T | Intron (SNP) | VAF 25/65 reads (38%) | catalogued as rs938748665, COSV58147143; called by muse, mutect2, varscan2
